CCDI case PBCMTZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/870743e2-be19-4f29-8646-da08a4267e7a

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Craniopharyngioma, adamantinomatous: ICD-O-3 morphology code: 9351/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.1 years (2,599 days).

Biospecimens (3 samples)
- Sample 0DVNX9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVNXD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVNYL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
